CCDI case PBCIJE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/f643e664-8a2a-42f1-8b1c-0d5736c378ad

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.4 years (4,886 days).

Biospecimens (3 samples)
- Sample 0DSYE8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DSYEF, 0DSYEO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
